Gene-level copy-number profile of tumor specimen HCM-BROD-1128-C15-06A from HCMI case HCM-BROD-1128-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G3; Age at diagnosis: 56.3 years (20,546 days).
Specimen HCM-BROD-1128-C15-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 99e581ce-e6c6-4d81-9e91-b7d5eda52331.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-1128-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/ffcab7b8-903b-4691-9d36-17879eacd4b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 348; copy number 1: 1,544; copy number 2: 32,736; copy number 3: 11,663; copy number 4: 7,445; copy number 5: 2,457; copy number 6: 1,511; copy number 7: 201; copy number 8: 340; copy number 9: 76; copy number 10: 44; copy number 11: 205; copy number 12: 32; copy number 13: 62; copy number 14: 26; copy number 15: 11; copy number 16: 52; copy number 17: 90; copy number 18: 13; copy number 21: 13; copy number 31: 35.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes (within-gene range 0–1): AC104164.2, MIR548BB.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,168 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,179,675–32,286,165, 11 genes, copy number 5: TXLNA, CCDC28B, AL049795.1, IQCC, DCDC2B, TMEM234, EIF3I, MTMR9LP, FAM167B, LCK, Metazoa_SRP.
- chr1:32,333,839–33,512,743, 46 genes, copy number 6: MARCKSL1, AL109945.1, TSSK3, FAM229A, BSDC1, GAPDHP20, AL356986.1, LRRC37A12P, RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A, ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20, AC115285.1.
- chr1:231,117,831–248,937,043, 386 genes, copy number 5 (broad region; genes not listed).
- chr2:206,939,518–208,266,074, 41 genes, copy number 5 (within-gene range 2–5): CPO, KLF7, MIR2355, KLF7-IT1, MYOSLID, MIR7845, AC007879.1, AC007879.3, AC007879.5, AC007879.2, AC007879.4, AC009226.1, LINC01802, MIR1302-4, CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17, CRYGEP, CRYGD, CRYGC, AC093698.1, CRYGB, CRYGA, C2orf80, RPSAP27, TPT1P2, IDH1.
- chr2:218,568,580–219,493,629, 58 genes, copy number 6 (within-gene range 4–6): CNOT9, RNU6-136P, PLCD4, ZNF142, BCS1L, RNF25, STK36, TTLL4, CYP27A1, AC009974.2, AC009974.1, PRKAG3, MIR9500, RPL23AP31, WNT6, WNT10A, LINC01494, RNU6-642P, AC097468.2, KRT8P30, CDK5R2, LINC00608, FEV, CRYBA2, MIR375, AC097468.1, CFAP65, IHH, MIR3131, AC097468.3, NHEJ1, AC068946.1, RN7SL764P, SLC23A3, CNPPD1, RETREG2, ZFAND2B, AC068946.3, ABCB6, AC068946.2, ATG9A, ANKZF1, GLB1L, STK16, TUBA4A, TUBA4B, DNAJB2, PTPRN, MIR153-1, AC114803.1, RESP18, AC053503.2, DNPEP, AC053503.1, DES, AC053503.3, AC053503.5, SPEG.
- chr2:229,357,629–229,923,239, 6 genes, copy number 5 (within-gene range 4–5): DNER, AC008273.1, RNU7-9P, AC007559.1, TRIP12, RNU6-613P.
- chr3:175,938,929–176,114,537, 5 genes, copy number 5: AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1.
- chr4:157,879,902–158,278,676, 13 genes, copy number 5: AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3, GASK1B, FAM198B-AS1, AC098679.5, NUDT19P5, AC098679.1, TMEM144, AIDAP2.
- chr5:21,323,873–45,895,970, 328 genes, copy number 6–8 (broad region; genes not listed).
- chr7:37,032–19,002,416, 297 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr8:92,460,539–95,811,254, 74 genes, copy number 5–13 (within-gene range 2–13) (broad region; genes not listed).
- chr8:104,330,324–105,804,539, 14 genes, copy number 5 (within-gene range 2–7): DPYS, DCSTAMP, AP003471.1, AP002847.1, MIR548A3, LRP12, NDUFA5P2, ZFPM2, AC012564.1, AC090142.2, AC090142.3, AC090142.1, AC021546.1, TMCC1P1.
- chr8:113,600,310–137,105,458, 284 genes, copy number 5–17 (broad region; genes not listed).
- chr9:12,134–89,850, 7 genes, copy number 6: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr10:14,061–38,783,108, 645 genes, copy number 6–7 (broad region; genes not listed).
- chr11:68,312,591–71,821,548, 94 genes, copy number 9–17 (broad region; genes not listed).
- chr11:72,836,745–73,142,318, 1 gene, copy number 6 (within-gene range 4–6): FCHSD2.
- chr11:72,940,498–74,669,117, 53 genes, copy number 6–12 (within-gene range 2–12): AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1, PGM2L1, HNRNPA1P40, AP001372.1, AP001085.1, MIR548AL, KCNE3, AP001372.3, CYCSP27, AP001372.4, LIPT2, AP001372.2, POLD3.
- chr11:83,213,005–85,627,922, 17 genes, copy number 6–17 (within-gene range 4–17): AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2, DLG2, DLG2-AS2, AP002370.1, LDHAL6DP, HNRNPA1P72, AP000852.1, AP001825.1, AP001825.2, AP001825.3, AP000857.2, AP000857.1, HNRNPCP6.
- chr11:87,037,844–87,328,824, 4 genes, copy number 6–10 (within-gene range 4–10): TMEM135, XIAPP2, AP002967.1, AP001102.1.
- chr11:90,193,614–90,226,538, 3 genes, copy number 11: AP000648.4, CHORDC1, AP002364.1.
- chr11:91,794,319–92,985,066, 15 genes, copy number 7: LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B.
- chr12:12,310–34,249,958, 834 genes, copy number 5–6 (broad region; genes not listed).
- chr12:38,906,451–40,570,832, 22 genes, copy number 6 (within-gene range 2–6): CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P.
- chr12:54,830,518–55,427,192, 25 genes, copy number 14: MUCL1, TESPA1, AC027287.2, NEUROD4, OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P, OR6C72P, OR6C6, OR6C5P, OR6C1, OR6C3, OR6C7P, OR6C75, OR6C71P, OR6C66P, OR6C73P, OR6C65, PHC1P1, OR6C76.
- chr12:55,608,043–56,270,966, 58 genes, copy number 11: OR6U2P, OR10P1, AC009779.4, OR10AE3P, PSMB3P1, AC009779.5, METTL7B, ITGA7, AC009779.3, BLOC1S1, RDH5, CD63, AC009779.2, Metazoa_SRP, AC009779.1, GDF11, SARNP, AC023055.1, AC073487.1, ORMDL2, DNAJC14, TMEM198B, MMP19, OLA1P3, GSTP1P1, PYM1, DGKA, AC025162.2, PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5.
- chr12:57,516,588–59,064,238, 50 genes, copy number 5–31 (within-gene range 2–31): DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2.
- chr12:61,708,259–62,279,150, 1 gene, copy number 5 (within-gene range 2–5): TAFA2.
- chr12:62,021,570–62,600,476, 10 genes, copy number 5: RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P.
- chr12:81,868,368–83,661,719, 14 genes, copy number 9–13: AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1.
- chr12:106,583,004–109,833,406, 73 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr13:71,913,704–77,844,145, 74 genes, copy number 5–21 (broad region; genes not listed).
- chr14:27,258,717–32,272,301, 79 genes, copy number 5–8 (broad region; genes not listed).
- chr14:32,879,246–32,882,830, 1 gene, copy number 6: AL049781.1.
- chr15:19,878,555–20,014,208, 14 genes, copy number 5: AC138701.1, RNU6-978P, AC138701.2, AC127381.2, IGHV1OR15-9, SLC20A1P3, IGHV1OR15-2, IGHV3OR15-7, IGHD5OR15-5A, IGHD4OR15-4A, IGHD3OR15-3A, IGHD2OR15-2A, IGHD1OR15-1A, FAM30B.
- chr19:30,228,290–30,909,155, 5 genes, copy number 6 (within-gene range 3–6): ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834.
- chr19:31,149,979–35,347,361, 132 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:37,371,061–41,137,308, 195 genes, copy number 5–11 (broad region; genes not listed).
- chr19:44,382,298–48,110,817, 188 genes, copy number 5–13 (within-gene range 2–13) (broad region; genes not listed).
- chr20:21,705,659–64,327,972, 990 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 500. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
